CPTAC case C3N-03452 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f54ddbc9-5251-4db0-ba83-0dae7d2ce40c

Demographics
Sex at birth: male; Race: white; Year of birth: 1940; Vital status: Dead; Days to death: 59 days; Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 77.3 years (28,247 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 59 days; Days to last follow up: 59 days.
   Pathology details: Greatest tumor dimension: 6 cm.

Follow-up (2 entries)
- Days to follow up: 59 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 22 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 59 days; Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 85 kg; Height: 179 cm; BMI: 26.53.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03452-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -20 days; Initial weight: 282 mg; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
  Slide C3N-03452-21: Section location: Frontal Lobe; Percent tumor nuclei: 80; Percent necrosis: 3.
- Sample C3N-03452-05: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -20 days; Initial weight: 265 mg; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-03452-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -20 days; Method of sample procurement: Blood Draw.
